Somatic mutation profile of tumor specimen TCGA-C5-A1M9-01A (aliquot TCGA-C5-A1M9-01A-11D-A13W-08) from TCGA case TCGA-C5-A1M9, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G3; Age at diagnosis: 46.6 years (17,020 days).
Specimen TCGA-C5-A1M9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c03d4231-9fe0-4eac-8292-a712280dc59c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A1M9-10A (Blood Derived Normal), aliquot TCGA-C5-A1M9-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b697a9d6-62fc-4cfe-b818-2c29bbbdee28

The open-access MAF lists 46 somatic variants for this specimen: 34 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 11, Nonsense Mutation 2, Frame Shift Ins 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.6259G>A p.G2087R | Missense Mutation (SNP) | VAF 45/140 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1553153748, COSV61371196, COSV61381160; ClinVar: other; called by muse, mutect2, varscan2
- ADAMTSL2 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.411); catalogued as rs961558552; called by muse, mutect2, varscan2
- BOD1L1 | c.7750A>G p.M2584V | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs555601532, COSV50046548; called by muse, mutect2, varscan2
- CBLB | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 100/258 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV51435752; called by muse, mutect2, varscan2
- CD244 | c.551A>G p.Y184C (on ENST00000368033 / NM_001166663.2; = p.Y179C on NM_016382.4) | Missense Mutation (SNP) | VAF 73/210 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.61); catalogued as COSV59241292; called by muse, mutect2, varscan2
- COL1A2 | c.2456G>A p.R819H | Missense Mutation (SNP) | VAF 56/208 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs773985005, COSV51964997; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- EIF4B | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.554); catalogued as COSV50407011; called by muse, mutect2, varscan2
- EZH2 | c.1075C>T p.P359S (on ENST00000460911 / NM_001203247.2; = p.P364S on NM_004456.5) | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.071); catalogued as COSV57461630; called by muse, mutect2, varscan2
- FBXW7 | c.1798G>A p.D600N (on ENST00000281708 / NM_001349798.2; = p.D520N on NM_018315.5) | Missense Mutation (SNP) | VAF 43/58 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55921359, COSV55925782, COSV55951044; called by muse, mutect2, varscan2
- FN1 | c.2509C>T p.P837S | Missense Mutation (SNP) | VAF 89/138 reads (64%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV60562649; called by muse, varscan2
- FN1 | c.2477C>G p.S826* | Nonsense Mutation (SNP) | VAF 91/151 reads (60%) | catalogued as COSV60562660; called by muse, varscan2
- KANK1 | c.2948G>A p.G983D | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.807); catalogued as COSV63215472; called by muse, mutect2, varscan2
- KLHL1 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.017); catalogued as rs776644824, COSV64773990, COSV64774969; called by muse, mutect2, varscan2
- LRP6 | c.872G>C p.G291A | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.386); catalogued as COSV53793256; called by muse, mutect2, varscan2
- NEURL4 | c.787C>T p.H263Y | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV59762971; called by muse, mutect2, varscan2
- OLFM2 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV53433219; called by muse, mutect2, varscan2
- PAPOLB | c.139C>T p.L47F | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs1428915415, COSV68203307; called by muse, mutect2, varscan2
- PDHA2 | c.716A>T p.D239V | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54781555; called by muse, mutect2, varscan2
- PRDM5 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 133/596 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs761027478, CM1512082, COSV53360890; called by muse, mutect2, varscan2
- PRUNE2 | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 74/128 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as rs752352425, COSV65027295; called by muse, mutect2, varscan2
- PSEN1 | c.151T>C p.S51P | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV56196636; called by muse, mutect2, varscan2
- PTAR1 | c.197C>G p.P66R | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); catalogued as COSV61209491; called by muse, mutect2, varscan2
- RPAP2 | c.1471C>G p.P491A | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV72101657; called by muse, mutect2, varscan2
- SLC22A8 | c.1012G>A p.G338S | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.241); catalogued as rs753503135, COSV60326854; called by muse, mutect2, varscan2
- SMAD4 | c.274C>T p.H92Y | Missense Mutation (SNP) | VAF 43/56 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61691170; called by muse, mutect2, varscan2
- SPAG1 | c.127C>A p.L43I | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as rs753165641, COSV52561336, COSV52563478; called by muse, mutect2, varscan2
- TAS2R19 | c.586C>G p.L196V | Missense Mutation (SNP) | VAF 100/191 reads (52%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.764); catalogued as COSV66828998; called by muse, varscan2
- THY1 | c.380T>G p.L127R | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs147718110, COSV52455178; called by muse, mutect2, varscan2
- TMEM47 | c.322C>T p.R108* | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as COSV52063660, COSV52067476; called by muse, mutect2, varscan2
- ZC3H12B | c.647A>G p.Q216R | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.589); catalogued as COSV59051105; called by muse, mutect2, varscan2
- CCL23 | c.258G>C p.E86D | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, varscan2
- CCL23 | c.215G>A p.C72Y | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- KMT2C | c.8584_8603del p.L2862Ffs*6 | Frame Shift Del (DEL) | VAF 83/190 reads (44%) | called by mutect2, pindel, varscan2
- PTMA | c.39_45+1dup | Frame Shift Ins (INS) | VAF 8/20 reads (40%) | called by mutect2, varscan2
- AOX1 | c.2745A>C p.P915= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as COSV101021985, COSV65983720; called by muse, mutect2, varscan2
- CDC42EP1 | c.600C>T p.L200= | Silent (SNP) | VAF 62/124 reads (50%) | catalogued as rs757076420, COSV50758366; called by muse, mutect2, varscan2
- CTNNA3 | c.1479C>T p.L493= | Silent (SNP) | VAF 139/220 reads (63%) | catalogued as COSV65615370; called by muse, mutect2, varscan2
- CYFIP1 | c.2682G>A p.L894= | Silent (SNP) | VAF 33/140 reads (24%) | catalogued as rs752649591; called by muse, mutect2, varscan2
- CYP7B1 | c.1323G>A p.P441= | Silent (SNP) | VAF 26/106 reads (25%) | catalogued as rs201281307, COSV100042659; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- FAM214A | c.1593G>A p.L531= | Silent (SNP) | VAF 75/128 reads (59%) | catalogued as COSV55926885; called by muse, mutect2, varscan2
- MAMLD1 | c.504C>T p.S168= | Silent (SNP) | VAF 11/126 reads (9%) | catalogued as rs782781651, COSV53380255; called by muse, mutect2
- SEC14L1 | c.96G>A p.L32= | Silent (SNP) | VAF 64/183 reads (35%) | catalogued as COSV66725018; called by muse, mutect2, varscan2
- SIPA1L2 | c.1629G>A p.L543= | Silent (SNP) | VAF 26/47 reads (55%) | catalogued as COSV53398573; called by muse, mutect2, varscan2
- ZNF536 | c.1041C>T p.C347= | Silent (SNP) | VAF 50/136 reads (37%) | catalogued as rs1200857229, COSV62833046; called by muse, mutect2, varscan2
- ZNF777 | c.1995G>A p.T665= | Silent (SNP) | VAF 84/175 reads (48%) | catalogued as rs1253330257, COSV56098739; called by muse, mutect2, varscan2
- IPCEF1 | c.74-25C>G | Intron (SNP) | VAF 30/68 reads (44%) | catalogued as COSV54542293, COSV54550731; called by muse, mutect2, varscan2
